CPTAC case C3L-02625 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1c5f10ce-d248-404e-be55-bf8e37db0240

Demographics
Sex at birth: male; Race: white; Year of birth: 1951; Vital status: Dead; Days to death: 489 days (1.3 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: Bulgaria.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 66.2 years (24,167 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 489 days (1.3 years); Progression or recurrence: no; Days to last follow up: 503 days (1.4 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 3 cm (a second GDC size field records 5 cm); Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 15; Margin status: Uninvolved.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 503 days (1.4 years); Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.
- Days to follow up: 503 days (1.4 years); Disease response: Progressive Disease; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 79 kg; Height: 173 cm; BMI: 26.4; FEV1/FVC before bronchodilator (%): 99.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 36; Cigarettes per day: 20; Tobacco smoking onset year: 1970; Tobacco smoking quit year: 2006; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 36.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02625-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 225 mg; Time between clamping and freezing: 32 minutes; Time between excision and freezing: 17 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02625-24: Section location: Left Lung; Percent tumor nuclei: 75; Percent necrosis: 5.
- Sample C3L-02625-08: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 175 mg; Time between clamping and freezing: 41 minutes; Time between excision and freezing: 26 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02625-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -8 days; Method of sample procurement: Blood Draw.
